Somatic mutation profile of tumor specimen TCGA-VS-A9UB-01A (aliquot TCGA-VS-A9UB-01A-22D-A42O-09) from TCGA case TCGA-VS-A9UB, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 54.0 years (19,737 days).
Specimen TCGA-VS-A9UB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42d75182-4b07-4eb9-a554-b6882807a291.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9UB-10A (Blood Derived Normal), aliquot TCGA-VS-A9UB-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76dd187e-cdff-45a2-afbc-175204f1fb90

The open-access MAF lists 112 somatic variants for this specimen: 85 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 26, Nonsense Mutation 4, Intron 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4394G>A p.G1465E | Missense Mutation (SNP) | VAF 87/164 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555473491, COSV52114921, COSV99269794; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.3533A>G p.Y1178C | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1555398515, CM098677, COSV100354833; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.495); catalogued as rs143685061; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACOX1 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762956777, COSV53136333; called by muse, mutect2
- ACSS1 | c.1915A>T p.R639W | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100053687; called by muse, mutect2, varscan2
- ACTN2 | c.1805T>C p.V602A | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV100856773; called by mutect2, varscan2
- ADRA1B | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1453420114, COSV100140196; called by muse, mutect2, varscan2
- APOBEC3F | c.698G>T p.W233L | Missense Mutation (SNP) | VAF 52/91 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV100415182; called by muse, mutect2, varscan2
- ARHGAP44 | c.1205T>C p.M402T | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV99310607; called by muse, mutect2, varscan2
- AUNIP | c.606T>A p.H202Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100961851; called by muse, mutect2, varscan2
- CAMTA1 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1242524547, COSV100348944; called by muse, mutect2, varscan2
- CCDC18 | c.3550C>T p.H1184Y (on ENST00000343253 / NM_001306076.1; = p.H1185Y on NM_206886.4) | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV100159504; called by muse, mutect2, varscan2
- CCNT2 | c.419T>C p.L140P | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99750572; called by muse, mutect2, varscan2
- CELF3 | c.884C>A p.P295H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.319); catalogued as COSV99310240; called by muse, mutect2, varscan2
- CFAP69 | c.1529A>T p.Q510L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100290049; called by muse, mutect2, varscan2
- CHAD | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs202147669; called by muse, mutect2, varscan2
- CHEK1 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99629601; called by muse, mutect2, varscan2
- CLSPN | c.2400C>A p.F800L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV99230787; called by muse, mutect2, varscan2
- COL4A2 | c.3749A>T p.Q1250L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs1173195289, COSV100847332; called by muse, mutect2, varscan2
- CTBP2 | c.166A>T p.T56S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV100456399; called by muse, mutect2, varscan2
- CXCL16 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs754219984, COSV99543468, COSV99543548; called by muse, mutect2, varscan2
- CYFIP2 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as COSV100556641; called by muse, mutect2, varscan2
- DDX31 | c.2104C>T p.H702Y | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.959); catalogued as COSV100936743; called by muse, mutect2, varscan2
- DEF8 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99240432; called by muse, mutect2, varscan2
- DLC1 | c.497T>C p.I166T | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV99362753; called by muse, mutect2, varscan2
- DMXL2 | c.8534A>G p.Y2845C | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99196291; called by muse, mutect2, varscan2
- EMC10 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.916); catalogued as COSV100618478; called by muse, mutect2, varscan2
- FAM124A | c.140T>C p.V47A (on ENST00000322475 / NM_001242312.2; = p.V83A on NM_145019.4) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99696268; called by muse, mutect2, varscan2
- FAM20A | c.905A>G p.Q302R | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.86); PolyPhen benign (0.023); catalogued as COSV99873313; called by muse, mutect2, varscan2
- FAT1 | c.10211C>G p.S3404* | Nonsense Mutation (SNP) | VAF 23/35 reads (66%) | catalogued as COSV101499314; called by muse, mutect2, varscan2
- FGF10 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.612); catalogued as rs200701392; called by muse, mutect2, varscan2
- FRMPD1 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs779949389, COSV100899309; called by muse, mutect2, varscan2
- GPCPD1 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.136); catalogued as COSV100980162; called by muse, mutect2, varscan2
- GUCY2F | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV99484906; called by muse, mutect2, varscan2
- IFNAR2 | c.1163T>G p.L388W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as COSV99269917; called by muse, mutect2, varscan2
- IMMT | c.2269C>G p.P757A | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.022); catalogued as COSV99606293; called by muse, mutect2, varscan2
- IQCH | c.2690G>C p.S897T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV100245729; called by muse, mutect2, varscan2
- ISM2 | c.417G>T p.R139S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.039); catalogued as COSV53634948, COSV99376608; called by muse, mutect2, varscan2
- JPH1 | c.1630G>A p.G544R | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs189087530, COSV60616308; called by muse, mutect2, varscan2
- KLHDC8A | c.97G>C p.V33L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100903816, COSV65678452; called by muse, mutect2, varscan2
- MAMLD1 | c.599T>A p.L200Q | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99475889; called by muse, mutect2, varscan2
- MAMSTR | c.1105C>A p.P369T (on ENST00000318083 / NM_001130915.2; = p.P266T on NM_182574.2) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV100540424; called by muse, mutect2, varscan2
- MAZ | c.1208C>G p.S403W | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99361064; called by muse, mutect2, varscan2
- MROH2B | c.2176A>T p.I726L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101270652; called by muse, mutect2, varscan2
- MUC5B | c.10075G>A p.A3359T | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs200708304, COSV71592990; called by muse, mutect2, varscan2
- MYH2 | c.2881G>A p.D961N | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99820018; called by muse, mutect2, varscan2
- NBEAL1 | c.7333A>G p.T2445A | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101355486; called by muse, mutect2, varscan2
- NLRP9 | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100243000; called by muse, mutect2, varscan2
- NOTCH1 | c.2057C>A p.P686H | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99487543; called by muse, mutect2, varscan2
- NPY5R | c.1217T>A p.V406E | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100642758; called by muse, mutect2, varscan2
- OTOF | c.4196A>T p.E1399V (on ENST00000272371 / NM_194248.3; = p.E632V on NM_004802.4) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV99717484; called by muse, mutect2, varscan2
- PDSS1 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.219); catalogued as COSV100697853; called by mutect2, varscan2
- PIGQ | c.1474A>T p.N492Y | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99216057; called by muse, mutect2
- PJA1 | c.1211C>A p.P404H (on ENST00000361478 / NM_145119.4; = p.P216H on NM_022368.5) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs780628980, COSV100824711, COSV64053527; called by muse, mutect2
- PNMA3 | c.1251T>A p.C417* | Nonsense Mutation (SNP) | VAF 13/89 reads (15%) | catalogued as COSV100937588; called by muse, mutect2, varscan2
- POU6F1 | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs777269426, COSV61327435; called by muse, mutect2, varscan2
- PPP2R1A | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1411009783, COSV100436242; called by muse, mutect2
- PPP2R3C | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.508); catalogued as rs904340799, COSV99808678; called by muse, mutect2, varscan2
- PPP6R3 | c.512C>G p.T171R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV55736759, COSV99676298; called by muse, mutect2, varscan2
- PRPH | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV99141970; called by muse, mutect2, varscan2
- RELN | c.8558G>T p.G2853V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59035461; called by muse, mutect2, varscan2
- RNF144B | c.236T>A p.V79E | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.065); catalogued as COSV99464541; called by muse, mutect2, varscan2
- S100A14 | c.69G>C p.E23D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as COSV100275220; called by muse, mutect2, varscan2
- SALL2 | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as rs756676999, COSV58104518; called by muse, mutect2, varscan2
- SCUBE3 | c.2725T>A p.F909I | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99234378; called by muse, mutect2, varscan2
- SELE | c.113C>A p.A38D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV100324716; called by muse, mutect2, varscan2
- SEMA4D | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450725971, COSV59396967; called by muse, mutect2, varscan2
- SH2D1B | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs747946218, COSV63392264; called by muse, mutect2, varscan2
- SLC25A42 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV59380293; called by muse, mutect2, varscan2
- SLC7A3 | c.1054T>C p.S352P | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV99979516; called by mutect2, varscan2
- ST8SIA5 | c.841T>G p.Y281D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | PolyPhen probably damaging (0.998); catalogued as COSV100164673; called by muse, mutect2, varscan2
- STAB2 | c.7111T>A p.L2371M | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101185914; called by muse, mutect2
- TAOK1 | c.60C>G p.F20L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.058); catalogued as COSV99913961; called by muse, mutect2, varscan2
- TCF7L2 | c.1079A>G p.Y360C (on ENST00000355995 / NM_001367943.1; = p.Y337C on NM_030756.5) | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99525677; called by muse, mutect2, varscan2
- TEX11 | c.1694T>C p.L565S (on ENST00000344304; = p.L550S on NM_031276.3) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100721626; called by muse, mutect2, varscan2
- TRAPPC12 | c.1872G>A p.M624I | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.376); catalogued as rs1168339386, COSV100160443; called by muse, mutect2, varscan2
- TTBK2 | c.3452C>A p.P1151H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV99141408; called by muse, mutect2, varscan2
- VPS52 | c.229-1G>A p.X77_splice | Splice Site (SNP) | VAF 7/39 reads (18%) | catalogued as COSV101460429; called by muse, mutect2, varscan2
- WASF3 | c.1396A>T p.K466* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100098588; called by muse, mutect2, varscan2
- WNT10B | c.1126T>A p.C376S | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99975909; called by muse, mutect2, varscan2
- ZHX2 | c.1036A>G p.T346A | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as COSV100072945; called by muse, mutect2, varscan2
- ZNF808 | c.1168A>G p.T390A | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV100707904; called by muse, mutect2, varscan2
- CASP8 | c.321_322del p.Q107Hfs*14 (on ENST00000432109 / NM_033355.3; = p.Q139Hfs*14 on NM_001228.4) | Frame Shift Del (DEL) | VAF 40/88 reads (45%) | called by mutect2, pindel, varscan2
- KIF20A | c.2492G>T p.G831V | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.243); called by muse, mutect2
- RHBDF2 | c.2156G>A p.G719D | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AP3B2 | c.216A>T p.S72= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV99916435; called by muse, mutect2, varscan2
- AR | c.1599A>T p.G533= | Silent (SNP) | VAF 6/126 reads (5%) | catalogued as COSV101018122; called by muse, mutect2
- BBX | c.1290C>T p.C430= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV100361152; called by muse, mutect2, varscan2
- BSCL2 | c.378C>T p.F126= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs1206021020, COSV99628170; called by muse, mutect2, varscan2
- CCR2 | c.355C>T p.L119= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99432329; called by muse, mutect2, varscan2
- GALNT9 | c.1470C>T p.L490= (on ENST00000328957 / NM_001122636.2; = p.L124= on NM_021808.3) | Silent (SNP) | VAF 68/129 reads (53%) | catalogued as COSV100201354; called by muse, mutect2, varscan2
- GJB3 | c.675G>T p.G225= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100973997; called by muse, mutect2, varscan2
- GPR22 | c.345C>T p.C115= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- GSN | c.1134G>A p.S378= | Silent (SNP) | VAF 83/122 reads (68%) | catalogued as rs145170518, COSV100375618; called by muse, mutect2, varscan2
- LRRC3B | c.279C>T p.L93= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV101185855; called by muse, mutect2, varscan2
- MROH2B | c.774G>C p.L258= | Silent (SNP) | VAF 50/98 reads (51%) | catalogued as COSV101270653; called by muse, mutect2, varscan2
- MTOR | c.3726G>C p.G1242= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV100816103, COSV63875470; called by muse, mutect2, varscan2
- NPBWR2 | c.525G>A p.T175= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs779117846, COSV100871109; called by muse, mutect2, varscan2
- PCNX1 | c.2880C>T p.Y960= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs182987509; called by muse, mutect2, varscan2
- PDPK1 | c.213G>A p.P71= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as rs79145795, COSV99239169; called by muse, mutect2, varscan2
- POLR1A | c.258A>T p.T86= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV99807553; called by muse, mutect2, varscan2
- RELN | c.1782T>A p.S594= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100633529; called by muse, mutect2, varscan2
- SETD1A | c.981C>T p.I327= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs1220499465, COSV99352866; called by muse, mutect2, varscan2
- STX17 | c.780T>A p.A260= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as COSV99407968; called by muse, varscan2
- TJP1 | c.372A>G p.V124= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV100632659; called by muse, mutect2, varscan2
- TUBB8 | c.750G>A p.L250= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as rs782796581; called by muse, mutect2
- WDR49 | c.75T>C p.F25= (on ENST00000308378 / NM_001366158.1; = p.F366= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/143 reads (15%) | catalogued as COSV100392556; called by muse, mutect2, varscan2
- WNT10B | c.1125G>T p.L375= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV99975910; called by muse, mutect2, varscan2
- ZC3H6 | c.765A>G p.K255= | Silent (SNP) | VAF 23/137 reads (17%) | catalogued as rs1310099916, COSV100674546; called by muse, mutect2, varscan2
- ZNF208 | c.324T>C p.H108= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as COSV101237005; called by muse, mutect2, varscan2
- ZNF530 | c.207C>T p.S69= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs529420510, COSV100252560, COSV60531911; called by muse, mutect2, varscan2
- NBPF11 | c.-548-2799G>A | Intron (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2
